Somatic mutation profile of tumor specimen TCGA-DX-A7EI-01A (aliquot TCGA-DX-A7EI-01A-11D-A33E-09) from TCGA case TCGA-DX-A7EI, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 78.3 years (28,610 days).
Specimen TCGA-DX-A7EI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7691ec3c-5af7-4f34-8b38-7fc6f3aec092.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A7EI-10A (Blood Derived Normal), aliquot TCGA-DX-A7EI-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4b1a744-5deb-4c7b-9ef5-1298aacc7748

The open-access MAF lists 32 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 23, Silent 6, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANGEL2 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.335); catalogued as COSV100853907; called by muse, mutect2, varscan2
- APC | c.3793G>T p.E1265* | Nonsense Mutation (SNP) | VAF 21/23 reads (91%) | catalogued as CM127463, COSV57329086, COSV57386299; called by muse, mutect2, varscan2
- B4GALNT1 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 136/791 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs200510000; called by muse, mutect2, varscan2
- C4BPB | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 54/84 reads (64%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs779242216, COSV99699872; called by muse, mutect2, varscan2
- CHMP4B | c.409G>C p.D137H | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99459608; called by muse, mutect2, varscan2
- CLPX | c.967A>G p.T323A | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100269285; called by muse, mutect2, varscan2
- CNST | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.382); catalogued as COSV100829988; called by muse, mutect2, varscan2
- CRTC2 | c.1046A>G p.N349S | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV100338814; called by muse, mutect2, varscan2
- CWH43 | c.860G>C p.G287A | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99892742; called by muse, varscan2
- FLNA | c.4387G>C p.V1463L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV100774258; called by muse, mutect2, varscan2
- IL17RD | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.059); catalogued as rs746780914, COSV99576533; called by muse, mutect2, varscan2
- ITGBL1 | c.1469G>A p.G490D | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101084534, COSV65934807; called by muse, mutect2, varscan2
- KCNA4 | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100068481, COSV60250841; called by muse, mutect2, varscan2
- MPDZ | c.5202del p.G1735Afs*2 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | catalogued as COSV59925862; called by pindel, varscan2
- MUC16 | c.42739T>C p.F14247L | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV101109570; called by muse, mutect2
- MXRA5 | c.5716G>C p.E1906Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.562); catalogued as COSV54224691; called by muse, mutect2, varscan2
- PIK3C2G | c.709G>T p.V237L | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99849313; called by muse, mutect2, varscan2
- RANBP17 | c.2165G>C p.R722T | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101206055; called by muse, mutect2, varscan2
- SLC9C2 | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV100876552; called by muse, mutect2, varscan2
- SPATA31D1 | c.3889G>A p.V1297M | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100782454; called by muse, mutect2, varscan2
- TRAF4 | c.1286A>G p.E429G | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0.426); catalogued as COSV99286352; called by muse, mutect2, varscan2
- TUBA3E | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.593); catalogued as COSV99919618; called by muse, mutect2, varscan2
- UGT8 | c.399C>A p.D133E | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100178950; called by mutect2, varscan2
- VPS50 | c.2705T>G p.F902C | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100004470; called by muse, mutect2, varscan2
- CST3 | c.218_231del p.L73Rfs*36 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- FRG2 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 100/123 reads (81%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABAT | c.400C>T p.L134= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV99190879; called by muse, mutect2, varscan2
- CYP39A1 | c.1409G>A p.*470= | Silent (SNP) | VAF 198/226 reads (88%) | catalogued as COSV99241836; called by muse, mutect2, varscan2
- KIAA1109 | c.2670C>G p.L890= | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as COSV99145686; called by muse, mutect2, varscan2
- LILRA4 | c.1374G>A p.L458= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as COSV52494605, COSV99392856; called by muse, mutect2, varscan2
- MXD3 | c.456C>T p.D152= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV100293439; called by muse, mutect2, varscan2
- SETDB1 | c.2208G>T p.R736= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV99643686; called by muse, mutect2
